Somatic mutation profile of tumor specimen TARGET-40-NAAGJV-01A (aliquot TARGET-40-NAAGJV-01A-01D) from TARGET case TARGET-40-NAAGJV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,784 days).
Specimen TARGET-40-NAAGJV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01deeb05-13e4-4666-8e97-d7a93828bafd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJV-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJV-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04587e84-05b2-44fb-a98d-44e4ac65d690

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B1 | c.2041G>C p.G681R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814964; called by muse, mutect2
- SRA1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1313668405; called by muse, mutect2, varscan2
- AUTS2 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- KDR | c.3851G>C p.G1284A | Missense Mutation (SNP) | VAF 412/1342 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, varscan2
- KDR | c.3987G>C p.L1329= | Silent (SNP) | VAF 540/1606 reads (34%) | catalogued as COSV55771413; called by muse, mutect2, varscan2
- KMT2B | c.4737T>G p.R1579= | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
